Somatic mutation profile of tumor specimen TCGA-FG-5965-02B (aliquot TCGA-FG-5965-02B-11D-A29Q-08) from TCGA case TCGA-FG-5965, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Mixed glioma; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 39.0 years (14,249 days).
Specimen TCGA-FG-5965-02B: Sample type: Recurrent Tumor; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) dce605b9-bc55-4474-b703-70c6946df269.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FG-5965-10A (Blood Derived Normal), aliquot TCGA-FG-5965-10A-01D-1893-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4d55d4a1-da7e-4f10-9d86-d84a974c0213

The open-access MAF lists 77 somatic variants for this specimen: 57 protein-altering or splice-affecting, 20 silent.
By variant classification: Missense Mutation 49, Silent 20, Frame Shift Del 3, Splice Site 2, Nonsense Mutation 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 14/73 reads (19%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- OTX2 | c.235G>A p.E79K (on ENST00000408990 / NM_172337.3; = p.E87K on NM_021728.4) | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs786205224, CM1411529, COSV59765795; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 63/127 reads (50%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 20/53 reads (38%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913343, CM010471, CM010473, CM951233, COSV52662066, COSV52670856, COSV52707054, COSV53164203; ClinVar: not provided / uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ACTN1 | c.169G>C p.E57Q | Missense Mutation (SNP) | VAF 20/79 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.143); catalogued as COSV51997783, COSV99518172; called by muse, mutect2, varscan2
- ADGRA3 | c.3583C>A p.P1195T | Missense Mutation (SNP) | VAF 34/106 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.815); catalogued as COSV99293524; called by muse, mutect2, varscan2
- ADGRE3 | c.1339A>G p.T447A | Missense Mutation (SNP) | VAF 21/119 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.708); catalogued as COSV53729639; called by muse, mutect2, varscan2
- AFF2 | c.3914G>A p.R1305H | Missense Mutation (SNP) | VAF 26/164 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.343); catalogued as rs1041916973, COSV53990241, COSV53998281; called by muse, mutect2, varscan2
- ANO2 | c.2378C>A p.T793N (on ENST00000356134 / NM_001278597.3; = p.T797N on NM_001278596.3) | Missense Mutation (SNP) | VAF 12/96 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.32); catalogued as COSV59015876; called by muse, mutect2, varscan2
- ASCC3 | c.6400G>C p.G2134R | Missense Mutation (SNP) | VAF 24/221 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as COSV100976749; called by muse, mutect2, varscan2
- ATRX | c.4838T>A p.L1613* | Nonsense Mutation (SNP) | VAF 15/47 reads (32%) | catalogued as COSV64874373, COSV64883894; called by muse, mutect2, varscan2
- B4GALNT4 | c.572C>T p.S191L | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100327758; called by muse, mutect2, varscan2
- BMP1 | c.1660C>T p.P554S | Missense Mutation (SNP) | VAF 30/122 reads (25%) | SIFT tolerated (0.2); PolyPhen benign (0.292); catalogued as COSV60478042; called by muse, mutect2, varscan2
- BVES | c.482A>G p.Y161C | Missense Mutation (SNP) | VAF 40/191 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1375067894, COSV100115092, COSV58947214; called by muse, mutect2, varscan2
- CAMTA1 | c.1101C>G p.N367K | Missense Mutation (SNP) | VAF 38/106 reads (36%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.257); catalogued as COSV57892728; called by muse, mutect2, varscan2
- CCKAR | c.374T>A p.V125E | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99810418; called by muse, mutect2, varscan2
- CDH1 | c.478C>T p.P160S | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55728659; called by muse, mutect2, varscan2
- CILP2 | c.2095C>T p.R699C | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs1302961723, COSV99364973; called by muse, mutect2, varscan2
- CPS1 | c.3927+2T>A p.X1309_splice | Splice Site (SNP) | VAF 12/51 reads (24%) | catalogued as COSV51806538; called by muse, mutect2, varscan2
- DCAF5 | c.400G>A p.E134K | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0.092); catalogued as COSV100432665, COSV58459135; called by muse, mutect2, varscan2
- DENND1B | c.587C>T p.A196V | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99344954; called by muse, varscan2
- EXOC1 | c.898G>C p.G300R | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100637952; called by muse, mutect2, varscan2
- EXOC1 | c.899G>A p.G300D | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.977); catalogued as COSV100637953; called by muse, mutect2, varscan2
- EYA3 | c.604A>G p.I202V | Missense Mutation (SNP) | VAF 17/121 reads (14%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.707); catalogued as rs755186429, COSV65816241; called by muse, mutect2, varscan2
- FAM186B | c.23A>C p.Q8P | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.573); catalogued as COSV99219652; called by muse, mutect2, varscan2
- FEZ1 | c.754C>T p.Q252* | Nonsense Mutation (SNP) | VAF 29/101 reads (29%) | catalogued as rs780307067, COSV99630913; called by muse, mutect2, varscan2
- FLG2 | c.3379G>T p.G1127C | Missense Mutation (SNP) | VAF 48/406 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.753); catalogued as COSV101166043; called by muse, mutect2, varscan2
- HAO2 | c.563G>A p.G188E | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0.013); catalogued as rs1407643865, COSV58040129; called by muse, varscan2
- HECW2 | c.4316C>G p.S1439C | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99648049; called by muse, mutect2, varscan2
- HYDIN | c.10901A>C p.E3634A | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.993); catalogued as COSV101157799; called by mutect2, varscan2
- KANK2 | c.310G>A p.G104S | Missense Mutation (SNP) | VAF 34/214 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.114); catalogued as rs147297854; called by muse, mutect2, varscan2
- LIMK1 | c.556C>T p.H186Y | Missense Mutation (SNP) | VAF 71/264 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100283323; called by muse, mutect2, varscan2
- LMOD2 | c.1159T>C p.S387P | Missense Mutation (SNP) | VAF 24/129 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.026); catalogued as COSV101505460; called by mutect2, varscan2
- LPL | c.642A>C p.R214S | Missense Mutation (SNP) | VAF 42/138 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60930776; called by muse, mutect2, varscan2
- MED15 | c.1873G>A p.V625I (on ENST00000263205 / NM_001003891.3; = p.V585I on NM_015889.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 58/209 reads (28%) | SIFT tolerated (0.18); PolyPhen benign (0.241); catalogued as rs1018320157, COSV53028325; called by muse, mutect2, varscan2
- MS4A1 | c.242G>A p.C81Y | Missense Mutation (SNP) | VAF 42/143 reads (29%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.883); catalogued as rs1565194450, COSV61941950; called by muse, mutect2, varscan2
- MYH8 | c.2982A>T p.K994N | Missense Mutation (SNP) | VAF 56/200 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV101238528; called by muse, mutect2, varscan2
- NAV3 | c.6648G>C p.W2216C (on ENST00000397909 / NM_001024383.2; = p.W2194C on NM_014903.6) | Missense Mutation (SNP) | VAF 15/101 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99893492; called by muse, mutect2, varscan2
- NUP210 | c.2071G>A p.G691S | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT tolerated (0.95); PolyPhen benign (0); catalogued as rs752915398, COSV99596188; called by muse, mutect2, varscan2
- PARP6 | c.82-2A>G p.X28_splice | Splice Site (SNP) | VAF 7/46 reads (15%) | catalogued as COSV99536280; called by muse, mutect2, varscan2
- PCOLCE2 | c.907C>T p.R303W | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.117); catalogued as rs749513617, COSV99930404; called by muse, mutect2, varscan2
- SCARA3 | c.238G>T p.V80L | Missense Mutation (SNP) | VAF 11/83 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.956); catalogued as COSV100106937; called by muse, varscan2
- SCN5A | c.1745C>T p.A582V | Missense Mutation (SNP) | VAF 33/259 reads (13%) | SIFT tolerated (0.59); PolyPhen benign (0.001); catalogued as COSV100349536, COSV61139789; called by muse, mutect2, varscan2
- SHC1 | c.136C>G p.L46V | Missense Mutation (SNP) | VAF 20/87 reads (23%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.952); catalogued as COSV58316094; called by muse, mutect2, varscan2
- SSB | c.896A>G p.K299R | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.239); catalogued as COSV99641805; called by muse, mutect2, varscan2
- STAG2 | c.2175G>T p.M725I | Missense Mutation (SNP) | VAF 23/133 reads (17%) | SIFT tolerated (0.42); PolyPhen benign (0.101); catalogued as COSV99494548; called by muse, mutect2, varscan2
- THUMPD3 | c.619T>C p.S207P | Missense Mutation (SNP) | VAF 7/83 reads (8%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.691); catalogued as COSV100560707; called by muse, mutect2
- TKTL1 | c.301G>C p.G101R | Missense Mutation (SNP) | VAF 64/388 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99474068; called by muse, mutect2, varscan2
- TMEM109 | c.208G>T p.G70W | Missense Mutation (SNP) | VAF 13/124 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99136319; called by muse, mutect2, varscan2
- TMEM109 | c.209G>T p.G70V | Missense Mutation (SNP) | VAF 13/123 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99136320; called by muse, mutect2, varscan2
- TRHDE | c.2212C>T p.P738S | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.069); catalogued as COSV53831780; called by muse, mutect2, varscan2
- VPS13B | c.3271A>G p.I1091V | Missense Mutation (SNP) | VAF 28/95 reads (29%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.952); catalogued as rs780930460, COSV62138195; called by muse, mutect2, varscan2
- XIAP | c.584G>C p.G195A | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT tolerated (0.25); PolyPhen benign (0.024); catalogued as COSV63022067; called by muse, mutect2, varscan2
- ARID2 | c.3488_3495dup p.G1166Ffs*10 | Frame Shift Ins (INS) | VAF 28/131 reads (21%) | called by mutect2, varscan2
- CYFIP1 | c.796del p.V266Sfs*8 | Frame Shift Del (DEL) | VAF 14/86 reads (16%) | called by mutect2, pindel
- PPP1R10 | c.157del p.I53Ffs*27 | Frame Shift Del (DEL) | VAF 23/91 reads (25%) | called by mutect2, pindel, varscan2
- VEZT | c.2164_2165del p.I722* | Frame Shift Del (DEL) | VAF 13/51 reads (25%) | called by mutect2, pindel, varscan2
- ACBD5 | c.279T>G p.P93= (on ENST00000375888 / NM_001352568.1; = p.P95= on NM_145698.5 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 18/57 reads (32%) | catalogued as COSV101022473; called by muse, mutect2, varscan2
- ADAM20 | c.30C>T p.I10= | Silent (SNP) | VAF 21/100 reads (21%) | catalogued as COSV56454588; called by muse, mutect2, varscan2
- ANO7 | c.2505C>T p.D835= (on ENST00000274979; = p.D781= on NM_001370694.2) | Silent (SNP) | VAF 45/335 reads (13%) | catalogued as rs149644243; called by muse, mutect2, varscan2
- CACNA2D2 | c.861G>A p.S287= | Silent (SNP) | VAF 19/69 reads (28%) | catalogued as rs771844125, COSV56559907; called by muse, mutect2, varscan2
- CARD11 | c.3420C>T p.G1140= | Silent (SNP) | VAF 16/133 reads (12%) | catalogued as rs1320638992, COSV101210803; called by muse, mutect2, varscan2
- CLCN1 | c.2745G>A p.G915= | Silent (SNP) | VAF 20/91 reads (22%) | catalogued as COSV100578300; called by muse, mutect2, varscan2
- GRIN3A | c.2523C>A p.A841= | Silent (SNP) | VAF 7/80 reads (9%) | catalogued as COSV100701668; called by muse, mutect2
- HS3ST4 | c.852T>A p.I284= | Silent (SNP) | VAF 37/183 reads (20%) | catalogued as COSV58809397; called by muse, mutect2, varscan2
- KCNH4 | c.1749G>A p.L583= | Silent (SNP) | VAF 10/41 reads (24%) | catalogued as COSV52917437, COSV99237613; called by muse, mutect2, varscan2
- KRT28 | c.726C>T p.N242= | Silent (SNP) | VAF 15/106 reads (14%) | catalogued as COSV60685042; called by muse, mutect2, varscan2
- LATS2 | c.483G>A p.G161= | Silent (SNP) | VAF 25/97 reads (26%) | catalogued as COSV101231633; called by mutect2, varscan2
- NSD3 | c.2076A>G p.R692= | Silent (SNP) | VAF 24/192 reads (13%) | catalogued as COSV100388786; called by muse, mutect2, varscan2
- OR2F1 | c.279A>T p.P93= | Silent (SNP) | VAF 64/245 reads (26%) | catalogued as rs779918144, COSV101231318; called by muse, mutect2, varscan2
- OSTF1 | c.477T>G p.L159= | Silent (SNP) | VAF 12/41 reads (29%) | catalogued as COSV60547069; called by muse, mutect2, varscan2
- PIBF1 | c.1785A>G p.L595= | Silent (SNP) | VAF 6/37 reads (16%) | catalogued as COSV58321947; called by muse, mutect2, varscan2
- RBM14 | c.138G>A p.A46= | Silent (SNP) | VAF 44/141 reads (31%) | catalogued as COSV100036876; called by muse, mutect2, varscan2
- RPS6KA6 | c.333T>C p.S111= | Silent (SNP) | VAF 8/54 reads (15%) | catalogued as COSV53118339; called by muse, mutect2, varscan2
- SEMA3D | c.954A>C p.A318= | Silent (SNP) | VAF 47/239 reads (20%) | catalogued as COSV99407080; called by muse, mutect2, varscan2
- TNRC6A | c.351G>A p.P117= | Silent (SNP) | VAF 21/128 reads (16%) | catalogued as rs748070015, COSV59368584; called by muse, mutect2, varscan2
- ZNF624 | c.1584T>C p.Y528= | Silent (SNP) | VAF 24/96 reads (25%) | catalogued as rs762489455, COSV100257345; called by muse, mutect2, varscan2
